Somatic mutation profile of tumor specimen TCGA-DJ-A2Q4-01A (aliquot TCGA-DJ-A2Q4-01A-21D-A18F-08) from TCGA case TCGA-DJ-A2Q4, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 53.9 years (19,689 days).
Specimen TCGA-DJ-A2Q4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2a97216-0f2d-4ee2-bce2-53417bc75944.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2Q4-10A (Blood Derived Normal), aliquot TCGA-DJ-A2Q4-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec2c4b44-9d34-4114-a209-5d3a2b27c123

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- NUP93 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | hotspot (GDC flag); catalogued as COSV57428872, COSV57434100; called by muse, mutect2, varscan2
- CD163 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63136346, COSV63137039; called by muse, mutect2
- CD248 | c.1727G>T p.R576I | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as COSV100256701, COSV60937801; called by muse, mutect2, varscan2
- DENND5A | c.3737A>G p.H1246R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60237804; called by muse, mutect2, varscan2
- DNAH3 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs750828186, COSV51786766; called by muse, mutect2, varscan2
- OR52N4 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as COSV57893001; called by muse, mutect2, varscan2
- SEC16A | c.383T>G p.L128W | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV51540436; called by muse, mutect2, varscan2
- TTLL7 | c.1715A>G p.N572S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53088856; called by muse, mutect2, varscan2
- CDH10 | c.261A>T p.G87= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV52597201; called by muse, mutect2, varscan2
